Somatic mutation profile of tumor specimen TCGA-A6-3810-01B (aliquot TCGA-A6-3810-01B-04D-A270-10) from TCGA case TCGA-A6-3810, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.0 years (22,999 days).
Specimen TCGA-A6-3810-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4c90c75-15d3-4dca-b0c9-808c681b23f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-3810-10A (Blood Derived Normal), aliquot TCGA-A6-3810-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/470708b0-6e9c-4dce-9241-d55f988a2b4f

The open-access MAF lists 133 somatic variants for this specimen: 101 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 30, Nonsense Mutation 5, Frame Shift Del 2, Splice Site 2, Intron 1, Nonstop Mutation 1, Splice Region 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 36/51 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACP4 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.332); catalogued as COSV99567720; called by muse, mutect2, varscan2
- ADCY7 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs369539863, COSV99576086; called by muse, mutect2, varscan2
- AFAP1 | c.770C>G p.S257* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100631636; called by muse, mutect2, varscan2
- AFF2 | c.305T>G p.V102G | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV100650262; called by muse, mutect2, varscan2
- ANGPTL5 | c.485A>T p.K162I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV100527826; called by muse, mutect2, varscan2
- ANK1 | c.4139C>T p.T1380M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs755216562, COSV55873916, COSV99225499; called by muse, mutect2, varscan2
- ANKLE1 | c.1505A>T p.K502M (on ENST00000394458; = p.K448M on NM_152363.6) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845739; called by muse, mutect2, varscan2
- AP3D1 | c.2714C>T p.P905L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs766493938, COSV100642748; called by muse, mutect2, varscan2
- APC | c.1762del p.V588Yfs*2 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as COSV57346229; called by mutect2, varscan2
- APC | c.3912del p.I1304Mfs*4 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as COSV57363654; called by mutect2, pindel, varscan2
- ASTL | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs144613777, COSV60904941; called by muse, mutect2, varscan2
- CDH20 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.418); catalogued as rs777777577, COSV99405595; called by muse, mutect2, varscan2
- CDHR1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60564616; called by muse, mutect2, varscan2
- CPAMD8 | c.1396G>A p.V466M (on ENST00000651564; = p.V419M on NM_015692.5) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs751013495, COSV52237252; called by muse, mutect2, varscan2
- CR1 | c.5828C>G p.T1943S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs1200358684, COSV65460559; called by muse, mutect2, varscan2
- CUL3 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs772779469, COSV52367627; called by muse, mutect2, varscan2
- DNAH8 | c.4769T>G p.V1590G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs1361990554, COSV100545726; called by muse, mutect2
- DST | c.19153G>A p.E6385K (on ENST00000361203 / NM_001374722.1; = p.E4082K on NM_015548.5) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376734906; called by muse, mutect2, varscan2
- ELOA2 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as rs773426243, COSV55303678; called by muse, mutect2, varscan2
- FAM83H | c.1007A>G p.E336G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1420741574, COSV101186995; called by muse, mutect2, varscan2
- FN1 | c.3370G>A p.G1124R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117299; called by muse, mutect2, varscan2
- FRAS1 | c.5261A>G p.Y1754C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV53629331; called by muse, mutect2, varscan2
- GABRB3 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54674522; called by muse, mutect2, varscan2
- GABRG3 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs779223196, COSV100407663; called by muse, mutect2, varscan2
- GOLIM4 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV58330869; called by muse, mutect2, varscan2
- GPC6 | c.1130C>A p.A377E | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100989109; called by muse, mutect2, varscan2
- GPR182 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs753611146, COSV55626380; called by muse, varscan2
- HAS1 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99708432; called by muse, mutect2, varscan2
- HK2 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51877382; called by muse, mutect2, varscan2
- HSF1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs148595793; called by muse, mutect2, varscan2
- INVS | c.2168A>G p.E723G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV99317627; called by muse, mutect2, varscan2
- KALRN | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV53761086; called by muse, mutect2, varscan2
- KDM6B | c.3874C>G p.L1292V | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as COSV99641639; called by muse, mutect2, varscan2
- KHDC3L | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs762594964, COSV100951108; called by muse, mutect2, varscan2
- KIRREL3 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.371); catalogued as rs779077392, COSV73107294; called by muse, mutect2, varscan2
- KPNA6 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65361266; called by muse, mutect2, varscan2
- MCM6 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV51467991; called by muse, mutect2, varscan2
- MMS22L | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51517886; called by muse, mutect2, varscan2
- NALCN | c.3582G>A p.P1194= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as rs201831882, COSV51951314; called by mutect2, varscan2
- NAV2 | c.3370G>A p.E1124K (on ENST00000396087 / NM_001244963.2; = p.E1101K on NM_145117.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774747436, COSV100217081; called by muse, mutect2, varscan2
- NEB | c.11662C>T p.P3888S | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV51437997; called by muse, mutect2, varscan2
- NID2 | c.2257+2T>G p.X753_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99356084, COSV99356653; called by muse, mutect2, varscan2
- NTRK2 | c.1693G>A p.D565N (on ENST00000323115 / NM_001369534.1; = p.D581N on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV52873111; called by muse, mutect2, varscan2
- OBP2A | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs139660402; called by muse, mutect2, varscan2
- OR5K3 | c.500C>A p.T167N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV101051652; called by mutect2, varscan2
- OR6C68 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); catalogued as COSV65563683; called by muse, mutect2
- PCDH11X | c.737A>G p.H246R | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV53487587; called by muse, mutect2, varscan2
- PCDHA3 | c.1401C>A p.N467K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs922814873, COSV100793520; called by muse, mutect2, varscan2
- PCDHB6 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs1453559918, COSV50690037; called by muse, mutect2, varscan2
- PFKFB1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | PolyPhen benign (0.054); catalogued as rs150213595, COSV66628924; called by muse, mutect2, varscan2
- PGR | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs150584881; called by muse, mutect2, varscan2
- PPFIA4 | c.3215A>G p.N1072S (on ENST00000447715; = p.N1073S on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs1377096342, COSV99690620; called by muse, mutect2, varscan2
- PRDM9 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV57010121; called by muse, mutect2, varscan2
- PSG9 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.665); catalogued as rs771822396, COSV52485241, COSV52486656; called by muse, mutect2, varscan2
- PSMC3 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs771618920, COSV54081878; called by muse, mutect2, varscan2
- PTCHD3 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs147881350; called by muse, mutect2, varscan2
- PTX4 | c.712G>C p.A238P (on ENST00000447419 / NM_001328608.2; = p.A233P on NM_001013658.1) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.188); catalogued as COSV53518213; called by muse, mutect2, varscan2
- RASA3 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100480672; called by muse, mutect2, varscan2
- REV3L | c.5671A>G p.M1891V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100725270; called by muse, mutect2, varscan2
- RGS18 | c.114A>C p.K38N | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV66509213; called by mutect2, varscan2
- RLF | c.4198G>A p.E1400K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs766622773, COSV101035448; called by muse, mutect2, varscan2
- ROS1 | c.3857G>A p.R1286H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs373090808, COSV63852270; called by muse, mutect2, varscan2
- RRP1B | c.2123C>T p.T708M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs766798880, COSV61479666; called by muse, mutect2, varscan2
- SBF1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); catalogued as rs578021802, COSV100817805; called by muse, mutect2, varscan2
- SCARF2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99839327; called by muse, mutect2, varscan2
- SCEL | c.1957T>A p.C653S (on ENST00000349847 / NM_144777.3; = p.C633S on NM_003843.4) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62994097; called by muse, mutect2
- SCN7A | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1420108843, COSV69273291; called by muse, mutect2, varscan2
- SI | c.5455G>T p.E1819* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100015804; called by muse, mutect2, varscan2
- SLC25A13 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as CM099600, COSV99673723; called by muse, mutect2, varscan2
- SLC38A7 | c.1286G>T p.S429I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.894); catalogued as COSV99543812; called by muse, mutect2, varscan2
- SLC39A5 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs199681035; called by muse, mutect2, varscan2
- SLC45A3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762101416, COSV65654711; called by muse, mutect2, varscan2
- SLC7A1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416819925, COSV101060217; called by muse, mutect2, varscan2
- SLFN13 | c.1552A>T p.S518C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV53194581; called by muse, mutect2
- SPART | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as rs1036407360, COSV100768526; called by muse, mutect2, varscan2
- SPON2 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376213322; called by muse, mutect2, varscan2
- SVIP | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780103291, COSV62602943; called by muse, mutect2, varscan2
- TNXB | c.7752C>A p.Y2584* (on ENST00000647633; = p.Y2337* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100926394; called by muse, mutect2, varscan2
- TRIM71 | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101070453; called by muse, mutect2, varscan2
- UNC13C | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as rs755928094, COSV52901372; called by muse, mutect2, varscan2
- UNC5D | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs545883862, COSV54802501; called by muse, mutect2, varscan2
- WHAMM | c.2360G>A p.R787K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54497887; called by mutect2, varscan2
- WWP1 | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV55361872; called by muse, mutect2, varscan2
- ZBTB46 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs375790108; called by muse, mutect2, varscan2
- ZEB2 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100356177; called by muse, mutect2, varscan2
- ZNF184 | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV53004996; called by muse, mutect2, varscan2
- ZNF354C | c.225A>T p.R75S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59609189; called by muse, varscan2
- ZNF559 | c.332G>C p.R111T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV57835075, COSV57836511; called by muse, mutect2, varscan2
- ZNF570 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57580136; called by muse, mutect2, varscan2
- ZNF649 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV61616909, COSV61617282; called by muse, mutect2, varscan2
- ZNF808 | c.2018A>T p.H673L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100707991; called by muse, mutect2, varscan2
- C1QL1 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.95); called by muse, varscan2
- COL19A1 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.14233T>G p.F4745V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MLXIP | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, varscan2
- PWWP2B | c.1773A>T p.*591Yext*4 | Nonstop Mutation (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- SCN1A | c.4122C>G p.Y1374* (on ENST00000303395 / NM_001202435.3; = p.Y1363* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- TEX37 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAF7 | c.1054A>T p.M352L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSR1 | c.1904-2A>G p.X635_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ADRA1D | c.900C>T p.S300= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- ANXA2R | c.546G>A p.A182= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs759777326, COSV59215072; called by muse, mutect2, varscan2
- CAPG | c.747A>G p.A249= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99809455; called by muse, mutect2, varscan2
- CCDC137 | c.819C>T p.H273= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs377260728; called by muse, mutect2, varscan2
- CHRNE | c.834C>T p.N278= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs996197218, COSV99545011; called by muse, mutect2, varscan2
- COL18A1 | c.2265G>A p.G755= (on ENST00000359759 / NM_130444.3; = p.G520= on NM_030582.4) | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV100700735; called by muse, mutect2, varscan2
- CYP2C9 | c.240T>C p.Y80= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as rs200794294, COSV53250876; called by muse, mutect2, varscan2
- CYP7B1 | c.249T>A p.V83= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- DNMT3B | c.2361A>G p.Q787= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs369258965; called by muse, mutect2, varscan2
- FASTKD1 | c.273T>C p.Y91= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as rs1275248373, COSV70007086; called by muse, mutect2, varscan2
- MLXIP | c.459G>A p.K153= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1312045153, COSV59836868; called by muse, mutect2, varscan2
- MYCBP2 | c.10638C>T p.V3546= (on ENST00000357337; = p.V3584= on NM_015057.5) | Silent (SNP) | VAF 38/333 reads (11%) | catalogued as COSV62029971; called by muse, mutect2, varscan2
- MYO1D | c.2496A>G p.P832= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV59018962; called by muse, mutect2, varscan2
- NEK1 | c.36A>G p.E12= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as COSV71457283; called by muse, mutect2, varscan2
- NOTCH4 | c.5866C>T p.L1956= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV100900716; called by muse, mutect2, varscan2
- OR10H2 | c.375C>A p.A125= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100008790; called by muse, mutect2, varscan2
- OR2M5 | c.550C>T p.L184= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV63546084, COSV63546697; called by muse, mutect2, varscan2
- OR4X1 | c.648C>T p.Y216= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV60723397; called by muse, mutect2, varscan2
- PARD3B | c.2124G>A p.S708= | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as rs200496137, COSV100593752; called by muse, mutect2, varscan2
- PCDHB1 | c.183G>A p.A61= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV60632074; called by muse, mutect2, varscan2
- PCDHB8 | c.2133G>A p.A711= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1554281623, COSV50753657; called by muse, mutect2, varscan2
- PYGL | c.1587T>C p.D529= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1171142071, COSV53587313; called by mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- SCAF4 | c.687T>C p.A229= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV54589947; called by muse, mutect2, varscan2
- SLC22A4 | c.1176G>A p.L392= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs779825520, COSV52359242; called by muse, mutect2, varscan2
- SPATA17 | c.6C>T p.A2= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV100861173; called by muse, mutect2, varscan2
- STAC3 | c.258C>T p.N86= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs148939626; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRIL | c.177C>T p.H59= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV59867564; called by muse, mutect2, varscan2
- ZBED9 | c.1467T>A p.T489= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV101509270; called by muse, mutect2, varscan2
- ZNF385B | c.1455G>A p.P485= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs758213417, COSV100416067; called by muse, mutect2, varscan2
- MIR412 | n.79G>A | RNA (SNP) | VAF 11/41 reads (27%) | catalogued as rs368964407; called by muse, mutect2, varscan2
- NDUFA10 | c.999+7892C>G | Intron (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99401483; called by muse, mutect2, varscan2
